Somatic mutation profile of tumor specimen C3L-06428-02 (aliquot CPT0335270006) from CPTAC case C3L-06428, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 79.7 years (29,124 days).
Specimen C3L-06428-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Back; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f990347-a852-4ffa-9caa-a6fd2f6c0fca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06428-31 (Blood Derived Normal), aliquot CPT0335240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c61886a-a5c8-4005-9153-5a977f9621a0

The open-access MAF lists 2,206 somatic variants for this specimen: 1,422 protein-altering or splice-affecting, 713 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,311, Silent 713, Nonsense Mutation 79, Intron 51, Splice Region 17, Splice Site 6, Frame Shift Del 4, 3'Flank 4, 3'UTR 4, 5'UTR 4, 5'Flank 4, RNA 4.

Variants (750 of 2,206; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 69/296 reads (23%) | catalogued as rs765429911, CM109595, COSV64671812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs397508342, CM024683, COSV50043054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2555G>A p.G852E | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs104886187, CM044604, CM990401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ECM1 | c.499T>A p.F167I | Missense Mutation (SNP) | VAF 125/551 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909116, CM031962, CM076159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 67/373 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RORC | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774357869, CM158000, COSV100562072, COSV59094013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 73/237 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.417); catalogued as COSV50961100; called by muse, mutect2, varscan2
- A1CF | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs866434111, COSV50957596; called by muse, mutect2, varscan2
- ABCA4 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866219294, COSV64671282; called by muse, mutect2, varscan2
- ABCB1 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs199779996, COSV55951981; ClinVar: drug response; called by muse, mutect2, varscan2
- ABCB5 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as COSV51709891; called by muse, mutect2
- ABCC2 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs765088337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 87/394 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs199732808, COSV100217541; called by muse, mutect2, varscan2
- ABCG4 | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1204493323; called by muse, mutect2, varscan2
- ACACA | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as rs543034212; called by muse, mutect2, varscan2
- ACAN | c.6019G>A p.D2007N | Missense Mutation (SNP) | VAF 50/544 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753033186, COSV61361206; ClinVar: uncertain significance; called by muse, mutect2
- ACKR1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 82/621 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1420667760; called by muse, mutect2, varscan2
- ACSM2A | c.1232G>C p.G411A (on ENST00000219054; = p.G332A on NM_001308169.2) | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV54591147; called by muse, mutect2, varscan2
- ACSM4 | c.800G>A p.W267* | Nonsense Mutation (SNP) | VAF 89/395 reads (23%) | catalogued as rs942332048, COSV68068786; called by muse, mutect2, varscan2
- ACSM5 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 70/503 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV59374875; called by muse, mutect2, varscan2
- ACSS3 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699191; called by muse, mutect2, varscan2
- ADAM18 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 92/392 reads (23%) | catalogued as COSV55843802; called by muse, mutect2, varscan2
- ADAM19 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 86/536 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as COSV57437442; called by muse, mutect2, varscan2
- ADAM28 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56099232; called by muse, mutect2, varscan2
- ADAM28 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 73/494 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs892008783, COSV56103002, COSV56103665; called by muse, mutect2, varscan2
- ADAM29 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 91/452 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs776510915, COSV63662151, COSV63662881; called by muse, mutect2, varscan2
- ADAM29 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63661589; called by muse, mutect2, varscan2
- ADAM29 | c.1770G>A p.M590I | Missense Mutation (SNP) | VAF 92/474 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs772443832, COSV63662119; called by muse, mutect2, varscan2
- ADAM33 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 82/548 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.299); catalogued as rs1162835338, COSV62935590; called by muse, mutect2, varscan2
- ADAM7 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1381308214; called by muse, mutect2, varscan2
- ADAMTS12 | c.2751C>A p.D917E | Missense Mutation (SNP) | VAF 103/502 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.555); catalogued as rs932033088, COSV61256443; called by muse, mutect2, varscan2
- ADCY10 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63238736; called by muse, varscan2
- ADCYAP1R1 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs1468869897; called by muse, mutect2, varscan2
- ADGB | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 66/369 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs1363166411; called by muse, mutect2, varscan2
- ADGRL3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1453660298, COSV72268560; called by muse, mutect2, varscan2
- ADGRV1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as COSV67985397; called by muse, mutect2, varscan2
- ADH1C | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV72463461; called by muse, mutect2, varscan2
- ADH7 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs753958832; called by muse, mutect2, varscan2
- AEBP1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 23/536 reads (4%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.027); catalogued as rs1343015840, COSV56257446; called by muse, mutect2
- AHI1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1270940407, COSV55634067; called by muse, mutect2, varscan2
- AHNAK2 | c.1996A>G p.K666E | Missense Mutation (SNP) | VAF 114/513 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as rs535172514; called by muse, mutect2, varscan2
- AKTIP | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1208224739; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALOXE3 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59075216; called by muse, mutect2, varscan2
- ALPL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 113/476 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs138587317, CM1512156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMY1C | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748751804, COSV64407770; called by muse, mutect2, varscan2
- ANK2 | c.8291G>A p.R2764K | Missense Mutation (SNP) | VAF 79/437 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV52172467; called by muse, mutect2, varscan2
- ANKRD18A | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 95/404 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV68803601, COSV68803607; called by muse, mutect2, varscan2
- ANKRD30A | c.1235G>A p.G412E (on ENST00000611781; = p.G356E on NM_052997.2) | Missense Mutation (SNP) | VAF 98/468 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1229987200, COSV64605641; called by muse, mutect2, varscan2
- ANKRD7 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs532626106, COSV54554860; called by muse, mutect2, varscan2
- ANO3 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56791506; called by muse, mutect2, varscan2
- AP2A2 | c.1833C>G p.I611M | Missense Mutation (SNP) | VAF 157/690 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs777993214, COSV59963402; called by muse, mutect2, varscan2
- APOBEC3B | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 73/413 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV59842468; called by muse, mutect2, varscan2
- ARFGEF3 | c.6325G>A p.A2109T | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs756877876; called by muse, mutect2, varscan2
- ARHGAP17 | c.2074C>T p.P692S (on ENST00000289968 / NM_001006634.3; = p.P614S on NM_018054.6) | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV51506502, COSV51510006; called by muse, mutect2, varscan2
- ARHGAP31 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51797772; called by muse, mutect2, varscan2
- ARHGAP33 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 133/514 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV99137931; called by muse, mutect2, varscan2
- ARHGEF35 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 79/486 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.101); catalogued as rs1465837045, COSV100967669; called by muse, mutect2, varscan2
- ARMC4 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as rs748401451; called by muse, mutect2, varscan2
- ARMC4 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV53463031; called by muse, mutect2, varscan2
- ARMC5 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 155/651 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1356422086, COSV51655690; called by muse, mutect2, varscan2
- ARNT2 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 105/459 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57582303; called by muse, mutect2, varscan2
- ARSF | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs751497726, COSV63838954; called by muse, mutect2, varscan2
- ASB10 | c.1339C>T p.R447C (on ENST00000420175 / NM_001142459.2; = p.R432C on NM_080871.4) | Missense Mutation (SNP) | VAF 43/721 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1302735729, COSV52000102; called by muse, mutect2
- ASCC2 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs529000348, COSV100316157; called by muse, mutect2, varscan2
- ASTN1 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1161068737, COSV56084029; called by muse, mutect2, varscan2
- ATG16L2 | c.1473-1G>A p.X491_splice | Splice Site (SNP) | VAF 76/336 reads (23%) | catalogued as rs1341268844; called by muse, mutect2, varscan2
- ATG2B | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63421577; called by muse, mutect2, varscan2
- ATP13A5 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 38/189 reads (20%) | catalogued as COSV60875657; called by muse, mutect2, varscan2
- ATP2B2 | c.1675G>A p.E559K (on ENST00000352432; = p.E525K on NM_001683.5) | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59505436; called by muse, mutect2, varscan2
- ATP8A2 | c.3499G>A p.G1167R | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1419528778, COSV99681988; called by muse, mutect2, varscan2
- ATRNL1 | c.3755G>A p.W1252* | Nonsense Mutation (SNP) | VAF 84/394 reads (21%) | catalogued as COSV58081798; called by muse, mutect2, varscan2
- ATXN2L | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs755975680, COSV100294254; called by muse, mutect2, varscan2
- BCL11B | c.2447G>A p.R816Q (on ENST00000357195 / NM_001282237.2; = p.R745Q on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/565 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100596030, COSV61740350; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BEX4 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 87/179 reads (49%) | catalogued as COSV65516150; called by muse, mutect2, varscan2
- BIRC6 | c.3055C>T p.L1019F | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.642); catalogued as rs750062611; called by muse, mutect2, varscan2
- BLZF1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138245508; called by muse, mutect2, varscan2
- BMP2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 71/363 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1356335204; called by muse, mutect2, varscan2
- BNIP5 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV101465251; called by muse, mutect2
- BPIFA1 | c.670T>C p.C224R | Missense Mutation (SNP) | VAF 99/465 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777978608; called by muse, mutect2, varscan2
- BPIFB6 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62755711; called by muse, mutect2
- BPIFC | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 102/519 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs528531150; called by muse, mutect2, varscan2
- BTBD8 | c.1825G>A p.E609K (on ENST00000636805 / NM_001376131.1; = p.E96K on NM_015237.4) | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.891); catalogued as COSV64883950; called by muse, mutect2, varscan2
- BTN2A1 | c.1507C>T p.L503F | Missense Mutation (SNP) | VAF 103/516 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1561873942, COSV57002093; called by muse, mutect2, varscan2
- C10orf71 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 73/416 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV60512078; called by muse, mutect2, varscan2
- C12orf40 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.22); catalogued as rs267603453, COSV61137277; called by muse, mutect2, varscan2
- C1S | c.848G>A p.W283* | Nonsense Mutation (SNP) | VAF 67/329 reads (20%) | catalogued as rs140559698, COSV61071275; called by muse, mutect2, varscan2
- C1orf87 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs762612884, COSV64596931; called by muse, mutect2, varscan2
- C2CD6 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs761495499, COSV53797381; called by muse, mutect2, varscan2
- C6 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs868229123, COSV54711348; called by muse, mutect2, varscan2
- C6orf136 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 146/644 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs751362069; called by muse, mutect2, varscan2
- C7 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 75/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038370285; called by muse, mutect2, varscan2
- C8B | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs766363026; called by muse, mutect2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, varscan2
- C9 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748961206, COSV99662708; called by muse, mutect2, varscan2
- CA11 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99320915; called by muse, mutect2, varscan2
- CA5A | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200681449, COSV59238863; called by muse, mutect2, varscan2
- CACNA1G | c.1140C>T p.I380= | Splice Region (SNP) | VAF 99/237 reads (42%) | catalogued as rs778924315; called by muse, mutect2, varscan2
- CACNA2D3 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 99/392 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as rs773282538, COSV99878155; called by muse, mutect2, varscan2
- CAMSAP3 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 153/674 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs779477941; called by muse, mutect2, varscan2
- CASD1 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.19); catalogued as COSV51970624, COSV99802072; called by muse, mutect2, varscan2
- CBLL2 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs144175358, COSV60369719; called by muse, mutect2, varscan2
- CCDC102B | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV60138478, COSV60152980; called by muse, mutect2, varscan2
- CCDC39 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56482080; called by muse, mutect2, varscan2
- CCDC80 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 99/475 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV52820378; called by muse, mutect2, varscan2
- CCIN | c.1301T>C p.L434S | Missense Mutation (SNP) | VAF 104/500 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs1258062013; called by muse, mutect2, varscan2
- CCR1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 97/390 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs758009218, COSV56121831; called by muse, mutect2, varscan2
- CCR3 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 92/429 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100656753; called by muse, mutect2, varscan2
- CCR6 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100551102, COSV59474435; called by muse, mutect2, varscan2
- CCSER1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 95/352 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as COSV61467725; called by muse, mutect2, varscan2
- CCT7 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 110/444 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.973); catalogued as rs547857492; called by muse, mutect2, varscan2
- CD163L1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.757); catalogued as COSV58013866; called by muse, mutect2, varscan2
- CD163L1 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 78/372 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as rs762788583, COSV58012022; called by muse, mutect2, varscan2
- CD6 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 104/437 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs773050570; called by muse, mutect2, varscan2
- CDC27 | c.1064A>C p.Q355P | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1046082236; called by muse, mutect2, varscan2
- CDC42BPA | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746097856, COSV62004278; called by muse, mutect2, varscan2
- CDH12 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66440474; called by muse, mutect2, varscan2
- CDO1 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51666209; called by muse, mutect2, varscan2
- CEACAM3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 104/449 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as rs1263320135; called by muse, mutect2, varscan2
- CECR2 | c.3992C>T p.S1331L (on ENST00000342247 / NM_001290047.2; = p.S1147L on NM_001290046.1) | Missense Mutation (SNP) | VAF 95/394 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV99377856; called by muse, mutect2, varscan2
- CELSR3 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 105/532 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559482165; called by muse, mutect2, varscan2
- CEMIP | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.343); catalogued as COSV55000234; called by muse, mutect2, varscan2
- CEP290 | c.7333G>A p.V2445I | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs756042946; called by muse, mutect2, varscan2
- CEP350 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 61/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs376245955; called by muse, mutect2, varscan2
- CER1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 113/518 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745943371; called by muse, mutect2, varscan2
- CES5A | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 83/428 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1442157395; called by muse, mutect2, varscan2
- CFAP61 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 139/577 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55622349; called by muse, mutect2, varscan2
- CFH | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 136/366 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV66413181; called by muse, mutect2, varscan2
- CGB1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as rs1232195649, COSV100031435; called by muse, mutect2, varscan2
- CHD5 | c.5128G>A p.G1710R | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769117837; called by muse, mutect2, varscan2
- CHGB | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 92/526 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as rs1313478981, COSV100973141, COSV66760190; called by muse, mutect2, varscan2
- CHGB | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 91/516 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100973144, COSV66761055; called by muse, mutect2, varscan2
- CHGB | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 75/542 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as rs1270122655, COSV66759525; called by muse, mutect2, varscan2
- CHRM1 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 100/486 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.361); catalogued as rs761435729, COSV61006875; called by muse, mutect2, varscan2
- CHST8 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 127/573 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1033408454, COSV52856961; called by muse, mutect2, varscan2
- CLCA1 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.41); catalogued as rs781010387; called by muse, mutect2, varscan2
- CLCN1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 115/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58370496; called by muse, mutect2, varscan2
- CLEC19A | c.90C>T p.A30= | Splice Region (SNP) | VAF 62/293 reads (21%) | catalogued as rs970945583; called by muse, mutect2, varscan2
- CLVS2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 99/445 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51568979; called by muse, mutect2, varscan2
- CNBD1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769372037; called by muse, mutect2, varscan2
- CNGB3 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 96/447 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV60697159; called by muse, mutect2, varscan2
- CNTN6 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63176583; called by muse, mutect2, varscan2
- COBLL1 | c.1795G>A p.E599K (on ENST00000392717; = p.E561K on NM_014900.5) | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV52063102; called by muse, mutect2, varscan2
- COL12A1 | c.7091C>T p.S2364L | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59398089; called by muse, mutect2, varscan2
- COL22A1 | c.3620G>A p.G1207E | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768207247, COSV57333070; called by muse, mutect2, varscan2
- COL24A1 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs199669304, COSV65308657; called by muse, mutect2, varscan2
- COL28A1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV68085202; called by muse, mutect2, varscan2
- CPXCR1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 107/207 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.57); catalogued as COSV52161262; called by muse, mutect2, varscan2
- CPZ | c.692C>T p.P231L (on ENST00000360986 / NM_001014447.3; = p.P220L on NM_003652.3) | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs866846974; called by muse, mutect2, varscan2
- CRYBB1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 133/652 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53232279; called by muse, mutect2, varscan2
- CSMD1 | c.3376G>A p.D1126N (on ENST00000520002; = p.D1125N on NM_033225.6) | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as rs1563296595, COSV59292050; called by muse, mutect2, varscan2
- CSMD1 | c.3181C>T p.H1061Y (on ENST00000520002; = p.H1060Y on NM_033225.6) | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV59325986; called by muse, mutect2, varscan2
- CSMD2 | c.5576C>T p.T1859I | Missense Mutation (SNP) | VAF 92/369 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99595156; called by muse, mutect2, varscan2
- CT55 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 118/242 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as rs782523634, COSV52277208; called by muse, mutect2, varscan2
- CUL1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV57390015; called by muse, mutect2, varscan2
- CUX2 | c.4000G>A p.D1334N | Missense Mutation (SNP) | VAF 125/423 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs753088571; called by muse, mutect2, varscan2
- CYLC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 118/537 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV66336737, COSV66337270; called by muse, mutect2, varscan2
- CYP2C19 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV64908528; called by muse, mutect2, varscan2
- CYP4F3 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 73/353 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745507534, COSV55407313; called by muse, mutect2
- DACH1 | c.1324C>T p.P442S (on ENST00000619232 / NM_001366712.1; = p.P390S on NM_080759.6) | Missense Mutation (SNP) | VAF 92/416 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs747753827, COSV57493215; called by muse, mutect2, varscan2
- DAPK2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1403509203, COSV56048960; called by muse, mutect2, varscan2
- DCAF8L2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 130/288 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV70552052; called by muse, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 74/337 reads (22%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- DCSTAMP | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 70/371 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV52577410; called by muse, mutect2, varscan2
- DDX60L | c.4618C>T p.P1540S | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52720772; called by muse, mutect2, varscan2
- DDX60L | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs533432548; called by muse, mutect2, varscan2
- DEFB112 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as rs267601067, COSV59182453; called by muse, mutect2, varscan2
- DEFB128 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747772243; called by muse, mutect2, varscan2
- DENND4B | c.3203C>T p.S1068F | Missense Mutation (SNP) | VAF 104/639 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1221924128; called by muse, mutect2, varscan2
- DGAT2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 98/428 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); catalogued as rs545718921; called by muse, mutect2, varscan2
- DIP2B | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as rs1232750966; called by muse, mutect2, varscan2
- DISP2 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 95/420 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs374870102; called by muse, mutect2, varscan2
- DLGAP1 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59786966; called by muse, mutect2, varscan2
- DNAH1 | c.7435C>T p.R2479* | Nonsense Mutation (SNP) | VAF 42/437 reads (10%) | catalogued as rs1268065530; called by muse, mutect2
- DNAH11 | c.13084G>A p.D4362N | Missense Mutation (SNP) | VAF 86/394 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs765948270, COSV60963315, COSV60974972; called by muse, mutect2, varscan2
- DNAH14 | c.2118G>A p.M706I (on ENST00000445597; = p.M735I on NM_001367479.1) | Missense Mutation (SNP) | VAF 73/320 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs865794262, COSV101464739; called by muse, mutect2, varscan2
- DNAH3 | c.9346G>A p.E3116K | Missense Mutation (SNP) | VAF 92/480 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54550653; called by muse, mutect2, varscan2
- DNAH5 | c.10864G>A p.E3622K | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV54250560; called by muse, mutect2, varscan2
- DNAH7 | c.8518G>A p.E2840K | Missense Mutation (SNP) | VAF 71/430 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV56753749; called by muse, mutect2, varscan2
- DNAJC17 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 89/391 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs762879970; called by muse, mutect2, varscan2
- DNM3 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 83/462 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1183572066, COSV62457525; called by muse, mutect2, varscan2
- DOCK3 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 93/409 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); catalogued as COSV56501219; called by muse, mutect2, varscan2
- DOCK6 | c.3718C>T p.R1240C | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs753969509; called by muse, mutect2, varscan2
- DPEP2NB | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs1300968391; called by muse, mutect2, varscan2
- DPEP2NB | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs924366236; called by muse, mutect2
- DPYS | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1014702313, COSV100037135; called by muse, mutect2, varscan2
- DQX1 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 101/528 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99283761; called by muse, mutect2, varscan2
- DSCAM | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.146); catalogued as rs957826009, COSV68032890; called by muse, mutect2, varscan2
- DSEL | c.3254C>T p.S1085L | Missense Mutation (SNP) | VAF 82/435 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as rs749309181, COSV59495548; called by muse, mutect2, varscan2
- DYNC1H1 | c.7023A>G p.I2341M | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100795729; called by muse, mutect2, varscan2
- E2F8 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 131/534 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769970471; called by muse, mutect2, varscan2
- EBLN1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 78/413 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs748174219; called by muse, mutect2, varscan2
- EDC4 | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1261013583, COSV59302782; called by muse, mutect2, varscan2
- EEF1A2 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 104/652 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV53208282; called by muse, varscan2
- ELF5 | c.539G>A p.R180Q (on ENST00000312319 / NM_198381.2; = p.R170Q on NM_001422.4) | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747223156; called by muse, mutect2, varscan2
- EMCN | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161432243, COSV56456826, COSV56463657; called by muse, mutect2, varscan2
- EML1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 102/401 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1270379365; called by muse, mutect2, varscan2
- EPHA6 | c.2308G>A p.D770N (on ENST00000389672 / NM_001080448.3; = p.D162N on NM_173655.4) | Missense Mutation (SNP) | VAF 90/387 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67561283; called by muse, mutect2, varscan2
- EPPK1 | c.4471C>T p.R1491W | Missense Mutation (SNP) | VAF 136/562 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs782125308; called by muse, mutect2, varscan2
- EPYC | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs115633176; called by muse, mutect2, varscan2
- ERAP2 | c.2411G>A p.G804E | Missense Mutation (SNP) | VAF 84/407 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs745408041; called by muse, mutect2, varscan2
- ERC2 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 79/445 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752396189, COSV55617332; called by muse, mutect2, varscan2
- ERG | c.1285C>T p.H429Y (on ENST00000398919 / NM_001243428.1; = p.H405Y on NM_004449.4) | Missense Mutation (SNP) | VAF 131/408 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV55737000; called by muse, mutect2, varscan2
- ERICH3 | c.2815G>C p.V939L | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100446074; called by muse, mutect2, varscan2
- ERICH3 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 110/472 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs1199533626, COSV58603692, COSV58614001; called by muse, mutect2, varscan2
- ESPN | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 92/404 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs370178224; called by muse, mutect2, varscan2
- EXOC1L | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 76/308 reads (25%) | catalogued as rs1426277040; called by muse, mutect2, varscan2
- EXOC3 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 102/475 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs555887025; called by muse, mutect2, varscan2
- EYS | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as CM1410765; called by muse, mutect2, varscan2
- F11 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 64/280 reads (23%) | catalogued as COSV99250969; called by muse, mutect2, varscan2
- FAAH | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99680381; called by muse, mutect2, varscan2
- FAM135B | c.3450G>A p.G1150= | Splice Region (SNP) | VAF 61/332 reads (18%) | catalogued as rs770702397; called by muse, mutect2
- FAM155A | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 118/644 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.929); catalogued as rs767748270; called by muse, mutect2, varscan2
- FAM214A | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV99957810; called by muse, mutect2, varscan2
- FAM83B | c.2779C>T p.H927Y | Missense Mutation (SNP) | VAF 82/393 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs377661351; called by muse, mutect2, varscan2
- FAM83B | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 63/319 reads (20%) | catalogued as rs367914924; called by muse, mutect2, varscan2
- FASN | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 224/518 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs767259814; called by muse, mutect2, varscan2
- FAT1 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 113/447 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs765011562; called by muse, mutect2, varscan2
- FAT4 | c.5362C>T p.R1788C | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs768397789, COSV58686429; called by muse, mutect2, varscan2
- FAT4 | c.11413C>T p.H3805Y | Missense Mutation (SNP) | VAF 98/447 reads (22%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.946); catalogued as rs755511559, COSV58682472; called by muse, mutect2, varscan2
- FBLN1 | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs267606275, COSV59936514; called by muse, mutect2
- FBN3 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.666); catalogued as rs376405342; called by muse, mutect2, varscan2
- FBXL7 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 99/415 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100308892; called by muse, mutect2, varscan2
- FBXW11 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV51615335; called by muse, varscan2
- FCRL5 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1558123953; called by muse, mutect2, varscan2
- FCRL5 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs1243936761, COSV62511728; called by muse, mutect2, varscan2
- FER1L5 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70069065; called by muse, mutect2, varscan2
- FERMT1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 80/401 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as CM074079; called by muse, varscan2
- FERMT1 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 84/378 reads (22%) | catalogued as COSV54098704, COSV99451883; called by muse, varscan2
- FFAR1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 148/668 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.696); catalogued as rs750236257, CM054758, COSV50055567; called by muse, mutect2, varscan2
- FGA | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs140959479; called by muse, mutect2, varscan2
- FGF14 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65936565; called by muse, mutect2, varscan2
- FGFR2 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs4647921; called by muse, mutect2, varscan2
- FGFR3 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 127/528 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV53392384; called by muse, mutect2, varscan2
- FGL2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.403); catalogued as rs763617359, COSV50381062; called by muse, mutect2, varscan2
- FILIP1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 91/400 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325850926; called by muse, mutect2, varscan2
- FLG2 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 96/381 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as rs763526275, COSV66171060; called by muse, mutect2, varscan2
- FLNB | c.3982C>T p.P1328S | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs765973664; called by muse, mutect2, varscan2
- FLNC | c.7550G>A p.G2517E | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.315); catalogued as COSV57959719; called by muse, mutect2, varscan2
- FMN2 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV60443207; called by muse, varscan2
- FMN2 | c.3364C>T p.P1122S | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV60427329; called by muse, mutect2, varscan2
- FNBP4 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99771975; called by muse, mutect2, varscan2
- FOSB | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 112/490 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV62278420; called by muse, mutect2, varscan2
- FOSL2 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 106/506 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99268491; called by muse, mutect2, varscan2
- FOXG1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 137/667 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1359529468; called by muse, mutect2, varscan2
- FOXJ1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 235/578 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1259607935; called by muse, mutect2, varscan2
- FOXR2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs772763910; called by muse, mutect2, varscan2
- FRRS1L | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 92/384 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.959); catalogued as rs1431832519; called by muse, mutect2, varscan2
- FRY | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV66564646; called by muse, mutect2, varscan2
- FSHR | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 122/497 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs762018429; called by muse, mutect2, varscan2
- FSIP2 | c.20375G>A p.R6792K | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58097320; called by muse, mutect2, varscan2
- FSIP2 | c.20485G>A p.E6829K | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV100553846, COSV58079049; called by muse, mutect2, varscan2
- GADL1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766744682, COSV56978852, COSV56978895; called by muse, mutect2, varscan2
- GALNT13 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.052); catalogued as rs868521163, COSV67211168; called by muse, mutect2, varscan2
- GARNL3 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as rs1438762426; called by muse, mutect2, varscan2
- GBP2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 117/431 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs754430142; called by muse, mutect2, varscan2
- GBP5 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as rs779805988, COSV58594294; called by muse, mutect2, varscan2
- GDF10 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 118/584 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as rs139931530; called by muse, varscan2
- GDF5 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 106/688 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs368321679; called by muse, mutect2, varscan2
- GEMIN5 | c.2674C>T p.H892Y | Missense Mutation (SNP) | VAF 81/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53563521; called by muse, mutect2, varscan2
- GHR | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV50118034, COSV50134231; called by muse, mutect2, varscan2
- GIMAP2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 105/498 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56234889; called by muse, mutect2, varscan2
- GJB4 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 91/428 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58356994; called by muse, mutect2, varscan2
- GK2 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774708528, COSV62626317; called by muse, varscan2
- GLB1L | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 66/309 reads (21%) | catalogued as rs771057382, COSV55475876; called by muse, mutect2, varscan2
- GNAS | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 120/643 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); catalogued as rs767833799; called by muse, mutect2, varscan2
- GPAT3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV52356538; called by muse, mutect2, varscan2
- GPATCH2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1446304669, COSV65128584; called by muse, mutect2, varscan2
- GPATCH4 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1168292554, COSV58041363; called by muse, mutect2, varscan2
- GPHN | c.949C>T p.R317C (on ENST00000315266 / NM_001377519.1; = p.R350C on NM_020806.5) | Missense Mutation (SNP) | VAF 95/427 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59488842; called by muse, mutect2, varscan2
- GPR141 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 83/393 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759565313, COSV57731278, COSV57732248; called by muse, mutect2, varscan2
- GPR149 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 98/443 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1159407846, COSV67671107; called by muse, mutect2, varscan2
- GPR158 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 100/456 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs749358424; called by muse, mutect2, varscan2
- GPR42 | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1273218691; called by muse, mutect2, varscan2
- GPR85 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 103/430 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs774052608, COSV51784185, COSV51785166; called by muse, mutect2, varscan2
- GRAMD4 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV63029165; called by muse, mutect2
- GRIA1 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53608199; called by muse, mutect2, varscan2
- GRIA2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52384411; called by muse, mutect2, varscan2
- GRID2IP | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 148/673 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs756362744, COSV101489698, COSV101489743; called by muse, mutect2, varscan2
- GRIN2D | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 94/422 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs1216030067; called by muse, mutect2, varscan2
- GRIN3A | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 118/527 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs769491656; called by muse, mutect2, varscan2
- GRIN3A | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 130/564 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1156422890; called by muse, mutect2, varscan2
- GRM8 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 179/424 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772324014, COSV58803533; called by muse, mutect2, varscan2
- GUCA1C | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 85/397 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.551); catalogued as rs370259737; called by muse, mutect2, varscan2
- GYPE | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs766974947; called by muse, mutect2, varscan2
- GYS2 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs750238325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 78/395 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139074313, COSV57147152; called by muse, mutect2, varscan2
- HAUS4 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV99247118; called by muse, mutect2, varscan2
- HAVCR1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369956191; called by muse, varscan2
- HDAC9 | c.3033G>A p.W1011* (on ENST00000441542 / NM_178425.3; = p.W1008* on NM_178423.3) | Nonsense Mutation (SNP) | VAF 55/275 reads (20%) | catalogued as COSV67770657; called by muse, mutect2, varscan2
- HDGFL1 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1327837895; called by muse, mutect2, varscan2
- HFM1 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 78/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748343941, COSV54022164; called by muse, mutect2, varscan2
- HMCN1 | c.9601C>T p.R3201C | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs369738413; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 73/374 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, mutect2, varscan2
- HOOK2 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 97/438 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV53403068; called by muse, mutect2, varscan2
- HPS1 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 115/564 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV57267066; called by muse, mutect2, varscan2
- HRH1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 47/536 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV67955484; called by muse, mutect2
- HS3ST2 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 105/464 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV54461098; called by muse, mutect2, varscan2
- HS3ST4 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 101/494 reads (20%) | catalogued as rs267604480, COSV58812934, COSV58826059; called by muse, mutect2, varscan2
- HSD17B2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 89/426 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs779171937, COSV52274204; called by muse, mutect2, varscan2
- HSPA12B | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs753113770; called by muse, varscan2
- HYAL3 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 148/581 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1553710814; called by muse, mutect2, varscan2
- HYDIN | c.14674G>A p.E4892K | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66642758; called by muse, mutect2, varscan2
- HYDIN | c.7501C>T p.P2501S | Missense Mutation (SNP) | VAF 156/689 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV59250042; called by muse, mutect2, varscan2
- IFFO2 | c.863T>C p.M288T | Missense Mutation (SNP) | VAF 64/347 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs541081873; called by muse, mutect2, varscan2
- IGFL3 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767094455; called by muse, mutect2, varscan2
- IGHMBP2 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54820723; called by muse, mutect2, varscan2
- IGKV2D-30 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as rs1169130478; called by muse, mutect2, varscan2
- IGKV3D-11 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as rs1343179073; called by muse, mutect2, varscan2
- IGLV3-9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 93/400 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as rs780422244; called by muse, mutect2, varscan2
- IGSF10 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 84/470 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV56791300; called by muse, mutect2, varscan2
- IL18 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV54781445; called by muse, mutect2, varscan2
- IL36A | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52083544; called by muse, varscan2
- IL36A | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs137983289, COSV52083029; called by muse, varscan2
- INTS10 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 64/323 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs200063039; called by muse, mutect2, varscan2
- INTS8 | c.2896T>G p.L966V | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57376393; called by muse, mutect2
- IQCA1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs776730195, COSV54496991; called by muse, mutect2, varscan2
- IRAG2 | c.2980G>A p.D994N (on ENST00000636465; = p.D39N on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.81); catalogued as COSV63140995; called by muse, mutect2, varscan2
- ISOC1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 107/480 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1187439406; called by muse, mutect2, varscan2
- ITFG1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs766871022, COSV57744631, COSV57751781; called by muse, mutect2, varscan2
- ITGBL1 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66008664; called by muse, mutect2, varscan2
- ITIH2 | c.2348G>A p.S783N | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.331); catalogued as rs750880202; called by muse, mutect2, varscan2
- ITIH5 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.309); catalogued as rs1225949231; called by muse, mutect2, varscan2
- ITPRID1 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.43); catalogued as rs144601428, COSV60079773; called by muse, varscan2
- IVL | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 139/563 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV64216791; called by muse, mutect2, varscan2
- JAKMIP1 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs530379301, COSV51525585; called by muse, mutect2, varscan2
- JCAD | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 127/554 reads (23%) | catalogued as rs1429956533; called by muse, mutect2, varscan2
- JPH3 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 121/465 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs1325702743; called by muse, mutect2, varscan2
- KBTBD3 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs1380590484; called by muse, mutect2, varscan2
- KCNA5 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 87/569 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as rs1403101707; called by muse, mutect2, varscan2
- KCNK13 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56410433; called by muse, mutect2, varscan2
- KCNK13 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 118/503 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.758); catalogued as COSV56411975; called by muse, mutect2, varscan2
- KCNQ3 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as COSV66469743; called by muse, mutect2, varscan2
- KCNT2 | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 141/403 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.244); catalogued as COSV54091179; called by muse, mutect2, varscan2
- KCNT2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.206); catalogued as COSV54080749; called by muse, mutect2, varscan2
- KCNU1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); catalogued as COSV67755141, COSV67758324; called by muse, mutect2
- KDM2A | c.2363A>G p.E788G | Missense Mutation (SNP) | VAF 118/492 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100445840; called by muse, mutect2, varscan2
- KIAA1217 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 98/416 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs568149946; called by muse, mutect2, varscan2
- KIF18A | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs1482375610; called by muse, mutect2, varscan2
- KIF21B | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 120/350 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs866579901, COSV59755415; called by muse, mutect2, varscan2
- KIF4B | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 109/519 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV70531874; called by muse, mutect2, varscan2
- KIFAP3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV63037267; called by muse, mutect2
- KIFC1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 98/477 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65737862; called by muse, varscan2
- KL | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 109/442 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66308518; called by muse, mutect2, varscan2
- KLK3 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 90/392 reads (23%) | catalogued as rs769439514; called by muse, mutect2, varscan2
- KRT32 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as rs746577723; called by muse, mutect2, varscan2
- LAMA3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772317627; called by muse, mutect2, varscan2
- LAMB4 | c.5050G>A p.G1684R | Missense Mutation (SNP) | VAF 38/445 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV52721731; called by muse, mutect2
- LAMB4 | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 125/262 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1011461063; called by muse, mutect2, varscan2
- LAMC2 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 96/568 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs773517261, COSV99917147; called by muse, mutect2, varscan2
- LAMP5 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 113/562 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55715320; called by muse, mutect2, varscan2
- LCT | c.2819G>C p.G940A | Missense Mutation (SNP) | VAF 118/533 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99928859; called by muse, mutect2, varscan2
- LEFTY1 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 120/714 reads (17%) | catalogued as rs200607882; called by muse, mutect2, varscan2
- LELP1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 105/545 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs1321315854; called by muse, mutect2, varscan2
- LHFPL5 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 98/481 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV64177716; called by muse, mutect2, varscan2
- LILRA1 | c.959-1G>A p.X320_splice | Splice Site (SNP) | VAF 77/370 reads (21%) | catalogued as rs1471105570, COSV52181705; called by muse, mutect2, varscan2
- LMX1A | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 90/455 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV54220278; called by muse, mutect2, varscan2
- LOX | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 70/378 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV50239356; called by muse, mutect2, varscan2
- LPA | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV60307977; called by muse, mutect2, varscan2
- LRFN2 | c.2326G>A p.G776R | Missense Mutation (SNP) | VAF 23/409 reads (6%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.466); catalogued as rs1023911263; called by muse, mutect2
- LRP1B | c.7541C>T p.S2514L | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs774854037, COSV67203044, COSV67250960; called by muse, mutect2, varscan2
- LRP1B | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs868652515, COSV67213914; called by muse, mutect2, varscan2
- LRP4 | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1332936896; called by muse, mutect2, varscan2
- LRRC7 | c.2257G>A p.D753N (on ENST00000651989 / NM_001370785.2; = p.D720N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/371 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as COSV99066425; called by muse, mutect2, varscan2
- LRRN3 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs371479262; called by muse, mutect2, varscan2
- LRRTM3 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100791562; called by muse, mutect2, varscan2
- LUZP2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1215809915, COSV100420969, COSV61199599; called by muse, mutect2, varscan2
- MAB21L4 | c.841G>A p.E281K (on ENST00000388934 / NM_001085437.3; = p.E113K on NM_024861.4) | Missense Mutation (SNP) | VAF 116/499 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1014185150, COSV56744671; called by muse, mutect2, varscan2
- MACF1 | c.7144C>T p.R2382C | Missense Mutation (SNP) | VAF 57/271 reads (21%) | catalogued as rs144972837; called by muse, mutect2, varscan2
- MAML1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 94/473 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV52984202, COSV52986426; called by muse, mutect2, varscan2
- MAN2A1 | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs746252123, COSV54846697; called by muse, mutect2, varscan2
- MAP10 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 52/827 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234096039; called by muse, mutect2
- MAP1B | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 82/409 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57100288; called by muse, mutect2, varscan2
- MAP3K14 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 154/435 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs755630489, COSV60923752; called by muse, mutect2, varscan2
- MAP3K5 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459888198, COSV62891624; called by muse, mutect2, varscan2
- MAP7D1 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1214100042; called by muse, mutect2, varscan2
- MASP2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV68896920, COSV68897580; called by muse, mutect2, varscan2
- MBTPS1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 95/498 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58571117; called by muse, mutect2, varscan2
- MCTP2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755280601, COSV100537685; called by muse, mutect2, varscan2
- MDGA2 | c.1972G>A p.D658N (on ENST00000399232 / NM_001113498.2; = p.D360N on NM_182830.4) | Missense Mutation (SNP) | VAF 104/427 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62088612; called by muse, mutect2, varscan2
- MEAK7 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 100/478 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1264877922, COSV59143022; called by muse, mutect2, varscan2
- MED23 | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 105/439 reads (24%) | catalogued as rs866208594, COSV63432802; called by muse, mutect2, varscan2
- MEGF8 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 142/564 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs996289561; called by muse, mutect2, varscan2
- MEI4 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 109/461 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs1213322205; called by muse, mutect2, varscan2
- MEOX1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 182/395 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745469637, COSV59357377; called by muse, mutect2, varscan2
- MEP1A | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1175277087; called by muse, mutect2, varscan2
- MGAM2 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.358); catalogued as rs1479962996; called by muse, mutect2, varscan2
- MICU3 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 70/417 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs200154899; called by muse, mutect2, varscan2
- MMP1 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 82/349 reads (23%) | catalogued as COSV59510466; called by muse, mutect2, varscan2
- MMP3 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs1555005554; called by muse, mutect2, varscan2
- MMRN2 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 114/578 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs772822797; called by muse, varscan2
- MOV10 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1557765803; called by muse, mutect2, varscan2
- MOV10L1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs775542421, COSV53171203; called by muse, mutect2, varscan2
- MPP7 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.179); catalogued as rs147738330; called by muse, mutect2, varscan2
- MREG | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1306153952, COSV54374596; called by muse, mutect2, varscan2
- MROH2B | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68183656; called by muse, mutect2, varscan2
- MROH9 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 51/391 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1553213796, COSV63012646; called by muse, mutect2, varscan2
- MROH9 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV63010437; called by muse, mutect2, varscan2
- MTNR1A | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 119/451 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV56155323; called by muse, mutect2, varscan2
- MTREX | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100043924; called by muse, mutect2, varscan2
- MUC16 | c.33340C>A p.P11114T | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.093); catalogued as COSV67449349; called by muse, mutect2, varscan2
- MUC16 | c.30440C>T p.S10147L | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.065); catalogued as COSV67473090; called by muse, mutect2, varscan2
- MUC16 | c.28282G>A p.E9428K | Missense Mutation (SNP) | VAF 99/435 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.281); catalogued as COSV67475644; called by muse, mutect2, varscan2
- MUC16 | c.26564C>T p.S8855F | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as rs1379980919, COSV67491580; called by muse, mutect2
- MUC16 | c.26468C>T p.S8823F | Missense Mutation (SNP) | VAF 122/502 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1214892158; called by muse, mutect2, varscan2
- MUC16 | c.24008C>T p.S8003L | Missense Mutation (SNP) | VAF 117/501 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); catalogued as COSV67450042; called by muse, mutect2, varscan2
- MUC16 | c.18770C>T p.P6257L | Missense Mutation (SNP) | VAF 87/398 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV101201445; called by muse, mutect2, varscan2
- MUC16 | c.13924G>A p.D4642N | Missense Mutation (SNP) | VAF 102/466 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); catalogued as rs766145562; called by muse, mutect2, varscan2
- MUC16 | c.10916G>A p.G3639E | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.328); catalogued as COSV67461534; called by muse, mutect2, varscan2
- MUC16 | c.9098G>A p.S3033N | Missense Mutation (SNP) | VAF 97/358 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as rs1568904813; called by muse, mutect2, varscan2
- MUC16 | c.6940G>A p.G2314R | Missense Mutation (SNP) | VAF 82/357 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101197413; called by muse, varscan2
- MUC4 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 166/718 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV62155221; called by muse, mutect2, varscan2
- MYH1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 101/343 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99876360; called by muse, mutect2, varscan2
- MYH13 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 85/313 reads (27%) | catalogued as rs527748477, COSV52826189, COSV52842467; called by muse, mutect2, varscan2
- MYH2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55431036; called by muse, mutect2, varscan2
- MYH6 | c.3981G>A p.A1327= | Splice Region (SNP) | VAF 29/174 reads (17%) | catalogued as rs904695058; called by muse, mutect2, varscan2
- MYO16 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as rs756747037, COSV62745391; called by muse, mutect2, varscan2
- MYO1F | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 91/477 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs369359209; called by muse, mutect2, varscan2
- MYO3B | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs1401312413; called by muse, mutect2, varscan2
- NALCN | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as COSV51919393; called by muse, mutect2, varscan2
- NDN | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV59359727; called by muse, mutect2
- NEB | c.8099C>T p.S2700F | Missense Mutation (SNP) | VAF 86/365 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1442943052; called by muse, mutect2, varscan2
- NEFL | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 47/479 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as rs1249514180, COSV99647917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK10 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs868641146, COSV58283758; called by muse, mutect2, varscan2
- NEXMIF | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 106/253 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV50021520; called by muse, mutect2, varscan2
- NEXMIF | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV50040979; called by muse, mutect2, varscan2
- NFASC | c.230G>A p.R77Q (on ENST00000339876 / NM_001378329.1; = p.R71Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757003214, COSV58365309; called by muse, mutect2, varscan2
- NFX1 | c.81T>A p.N27K | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs775981113, COSV100581920; called by muse, mutect2, varscan2
- NIBAN2 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 118/505 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs368668074, COSV55942823; called by muse, mutect2, varscan2
- NID2 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 83/401 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs746625647; called by muse, varscan2
- NIF3L1 | c.343C>T p.R115W (on ENST00000409020 / NM_001369444.1; = p.R88W on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/443 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs777573769; called by muse, mutect2, varscan2
- NINJ1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 132/526 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64922677; called by muse, mutect2, varscan2
- NLRP9 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV60462053; called by muse, mutect2, varscan2
- NONO | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52136998, COSV52138484; called by muse, mutect2, varscan2
- NPAP1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 125/442 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV61511677; called by muse, mutect2, varscan2
- NPAP1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 95/480 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1441786912, COSV61506747; called by muse, mutect2, varscan2
- NPC1L1 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56923357; called by muse, mutect2
- NPY1R | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs750677522; called by muse, mutect2, varscan2
- NPY4R | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782120446, COSV65397418; called by muse, mutect2, varscan2
- NR2E3 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as rs1283868328, COSV58908113; called by muse, mutect2, varscan2
- NR3C1 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196278; called by muse, mutect2, varscan2
- NREP | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1192701096, COSV67401246; called by muse, mutect2, varscan2
- NRK | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 109/257 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as rs375984803; called by muse, mutect2, varscan2
- NRXN3 | c.3163G>A p.E1055K (on ENST00000335750 / NM_001330195.2; = p.E682K on NM_004796.6) | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59794308; called by muse, mutect2, varscan2
- NSDHL | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs370277218; called by muse, mutect2, varscan2
- NSMF | c.1174G>A p.E392K (on ENST00000371475 / NM_001130969.3; = p.E390K on NM_015537.4) | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs1270783779; called by muse, mutect2, varscan2
- NTPCR | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs759051611, COSV64052222; called by muse, mutect2, varscan2
- NTRK3 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs574695821, COSV58132749; called by muse, mutect2, varscan2
- NWD1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as COSV60337354; called by muse, mutect2, varscan2
- NXPE2 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769161696; called by muse, mutect2, varscan2
- NYNRIN | c.4555G>A p.E1519K | Missense Mutation (SNP) | VAF 110/452 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs761134037; called by muse, mutect2, varscan2
- OLFM3 | c.875G>A p.G292E (on ENST00000338858 / NM_001288821.1; = p.G272E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58796045; called by muse, varscan2
- OPN3 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 63/413 reads (15%) | catalogued as rs1446302960, COSV100087786; called by muse, mutect2, varscan2
- OPRM1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57675705; called by muse, mutect2
- OR10A6 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 100/540 reads (19%) | catalogued as rs267603211, COSV59164785; called by muse, mutect2, varscan2
- OR10C1 | c.808G>A p.A270T (on ENST00000622521; = p.A268T on NM_013941.3) | Missense Mutation (SNP) | VAF 154/770 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1202208449; called by muse, mutect2, varscan2
- OR10G7 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 123/537 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1480229259, COSV100389941, COSV57866127; called by muse, mutect2, varscan2
- OR10J1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373330432, COSV101419901, COSV71128120; called by muse, mutect2, varscan2
- OR10J3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 112/639 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs867791135, COSV59953822; called by muse, mutect2, varscan2
- OR10J5 | c.733A>C p.T245P | Missense Mutation (SNP) | VAF 110/590 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776796325; called by muse, mutect2, varscan2
- OR10T2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 85/465 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1436627508; called by muse, mutect2, varscan2
- OR13A1 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 102/521 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65573724; called by muse, mutect2, varscan2
- OR13C4 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 87/369 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52925650; called by muse, mutect2, varscan2
- OR13C9 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 122/525 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV52241501; called by muse, mutect2, varscan2
- OR14A16 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV62926418; called by muse, mutect2, varscan2
- OR14K1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs1472766835; called by muse, mutect2, varscan2
- OR2A12 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV68821806; called by muse, varscan2
- OR2A2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 91/499 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs759840581, COSV68870991, COSV68871204; called by muse, mutect2, varscan2
- OR2F2 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 98/612 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV68833072; called by muse, mutect2, varscan2
- OR2G6 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 66/472 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58573950; called by muse, mutect2, varscan2
- OR2H1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 162/746 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193829610, COSV65810295; called by muse, mutect2, varscan2
- OR2M3 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 137/364 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs769867138, COSV71759339; called by muse, mutect2, varscan2
- OR4C13 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV73648600; called by muse, mutect2, varscan2
- OR4C15 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 91/384 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs769319726, COSV58955625; called by muse, mutect2, varscan2
- OR4C46 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV60218496; called by muse, mutect2, varscan2
- OR4L1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs369912800; called by muse, mutect2, varscan2
- OR4M1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 57/523 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV60062977; called by muse, mutect2, varscan2
- OR51T1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 101/448 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs373780146; called by muse, mutect2, varscan2
- OR51V1 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs779888708, COSV58316111; called by muse, mutect2, varscan2
- OR52A5 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV56614860; called by muse, mutect2, varscan2
- OR52N4 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 106/518 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1000198692; called by muse, mutect2, varscan2
- OR5B12 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 116/486 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as COSV56905030, COSV56906809; called by muse, mutect2, varscan2
- OR5B12 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 81/465 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); catalogued as COSV56906126; called by muse, mutect2, varscan2
- OR5B17 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 100/372 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as COSV62160702; called by muse, mutect2, varscan2
- OR5R1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 102/453 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1187689381, COSV56571727; called by muse, mutect2, varscan2
- OR6K6 | c.972G>A p.M324I (on ENST00000368144; = p.M300I on NM_001005184.1) | Missense Mutation (SNP) | VAF 83/450 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV63744363; called by muse, mutect2, varscan2
- OR7D2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV60141285; called by muse, mutect2, varscan2
- OR9G4 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 105/522 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778395992, COSV57249858; called by muse, mutect2, varscan2
- OSMR | c.290G>A p.W97* | Nonsense Mutation (SNP) | VAF 88/372 reads (24%) | catalogued as COSV57081308; called by muse, mutect2, varscan2
- OTOF | c.5193G>A p.K1731= (on ENST00000272371 / NM_194248.3; = p.K964= on NM_004802.4) | Splice Region (SNP) | VAF 82/376 reads (22%) | catalogued as rs1249251093; called by muse, mutect2, varscan2
- OTOL1 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60006253; called by muse, mutect2, varscan2
- OTOL1 | c.518-1G>A p.X173_splice | Splice Site (SNP) | VAF 53/225 reads (24%) | catalogued as rs1395165977; called by muse, mutect2, varscan2
- OTOL1 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60006228; called by muse, mutect2, varscan2
- P3H2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60029284; called by muse, varscan2
- PACSIN2 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 63/323 reads (20%) | catalogued as rs775404651; called by muse, mutect2, varscan2
- PAK5 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868564987, COSV62019951; called by muse, mutect2, varscan2
- PAK5 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 45/501 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs773981325, COSV62025752; called by muse, mutect2
- PAPPA | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 86/511 reads (17%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.994); catalogued as rs771878792; called by muse, mutect2, varscan2
- PAPPA2 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100868379, COSV62798918; called by muse, varscan2
- PAPPA2 | c.4445G>A p.G1482E | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs754629582, COSV62807009; called by muse, varscan2
- PARP14 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1244994998; called by muse, mutect2, varscan2
- PCDHA1 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 123/545 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1332112190, COSV100974416; called by muse, mutect2, varscan2
- PCDHA10 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 109/415 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56544401; called by muse, mutect2, varscan2
- PCDHA4 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.105); catalogued as rs558715293, COSV63542286; called by muse, mutect2, varscan2
- PCDHA9 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV65333893; called by muse, mutect2, varscan2
- PCDHGA4 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54056472; called by muse, mutect2
- PCDHGB1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 131/488 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1315943031; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 92/474 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2
- PCDHGB5 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 132/528 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as COSV53919558; called by muse, mutect2, varscan2
- PCMTD2 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 148/739 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55059186; called by muse, mutect2, varscan2
- PCSK1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 92/390 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990328651, COSV60735780; called by muse, mutect2, varscan2
- PDE1B | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs749477163, COSV99226270; called by muse, mutect2, varscan2
- PDE4B | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 53/336 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV100303091; called by muse, mutect2, varscan2
- PDE6B | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 118/541 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.209); catalogued as COSV99728608; called by muse, mutect2, varscan2
- PGLYRP3 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs749236657; called by muse, mutect2, varscan2
- PHACTR1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 86/467 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100276308; called by muse, mutect2, varscan2
- PHC2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 92/495 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs370430442; called by muse, mutect2, varscan2
- PHKA1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782696568, COSV59807294; called by muse, mutect2, varscan2
- PIGQ | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as rs377161206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 61/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61871225; called by muse, mutect2, varscan2
- PKHD1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 97/372 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868748445; called by muse, mutect2, varscan2
- PKHD1L1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.428); catalogued as rs540931167; called by muse, mutect2, varscan2
- PKHD1L1 | c.3749G>A p.R1250Q | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as rs560449366, COSV65747201; called by muse, mutect2
- PKIA | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs536361273, COSV61914497; called by muse, mutect2, varscan2
- PLCB1 | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100572310; called by muse, mutect2, varscan2
- PLCB4 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 103/550 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1418844892, COSV53794026; called by muse, mutect2, varscan2
- PLG | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 77/391 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as rs576737789, COSV57514358; called by muse, mutect2, varscan2
- PLVAP | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 134/549 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1280885279, COSV53085913, COSV53086281; called by muse, mutect2, varscan2
- PMFBP1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 133/515 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52827687, COSV99400330; called by muse, mutect2, varscan2
- PMFBP1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as rs778219933; called by muse, varscan2
- PNLIPRP2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.31); catalogued as COSV53945938; called by muse, mutect2, varscan2
- POF1B | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs143029658, COSV53140998; called by muse, mutect2, varscan2
- POM121L12 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 122/538 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs764722281, COSV68692179; called by muse, mutect2, varscan2
- POM121L12 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 138/548 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV68692140; called by muse, mutect2, varscan2
- POU5F2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 105/472 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1377123977; called by muse, mutect2, varscan2
- PPP1R15A | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 110/493 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs200986283; called by muse, mutect2, varscan2
- PPP1R16B | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 27/450 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV55379520; called by muse, mutect2
- PPP3R2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 114/479 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); catalogued as rs773945805; called by muse, mutect2, varscan2
- PRAME | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 101/596 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1340569390, COSV67162552; called by muse, mutect2, varscan2
- PRB2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 144/732 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs770351255, COSV66982551; called by muse, varscan2
- PRB3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs905255477, COSV54393040; called by muse, mutect2, varscan2
- PRKACG | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 103/459 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV55251112; called by muse, mutect2, varscan2
- PRKN | c.1184A>C p.E395A | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV58251730; called by muse, mutect2, varscan2
- PRPH2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 79/386 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV57837431; called by muse, mutect2, varscan2
- PRR23B | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 88/551 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.456); catalogued as COSV100272144; called by muse, mutect2, varscan2
- PRR23B | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 169/651 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs1414457250; called by muse, mutect2, varscan2
- PSG11 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs375462400; called by muse, mutect2, varscan2
- PTCHD3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 109/453 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV71256317; called by muse, mutect2, varscan2
- RAD51AP2 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101208377, COSV101208418; called by muse, mutect2, varscan2
- RANGAP1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62362501; called by muse, mutect2
- REPS1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57813349; called by muse, mutect2, varscan2
- RFPL4AL1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 91/466 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1290347939; called by muse, mutect2, varscan2
- RFTN1 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 113/527 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as rs865839274; called by muse, mutect2, varscan2
- RFX6 | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 119/471 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs763502980, COSV60583414; called by muse, mutect2, varscan2
- RGS7 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs1316442705, COSV58532520; called by muse, mutect2, varscan2
- RHAG | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs747990208; called by muse, mutect2, varscan2
- RHPN2 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 85/349 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54281166; called by muse, mutect2, varscan2
- RIMS3 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 108/483 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs765042870, COSV101013297; called by muse, mutect2, varscan2
- RLIM | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 162/373 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV60328973; called by muse, varscan2
- RNF103 | c.1987C>G p.R663G | Missense Mutation (SNP) | VAF 105/423 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV52893556; called by muse, mutect2, varscan2
- RNF182 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 105/470 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs1406350850; called by muse, mutect2, varscan2
- RNF214 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs373694544; called by muse, mutect2, varscan2
- RNF215 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1310986633; called by muse, mutect2, varscan2
- RNLS | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 107/426 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59292415; called by muse, mutect2, varscan2
- RP1 | c.1922G>A p.R641K | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55112847, COSV55126695; called by muse, mutect2, varscan2
- RTF2 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 95/513 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as rs1276602809; called by muse, mutect2, varscan2
- RTL1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1190567087, COSV66017395; called by muse, varscan2
- RYR1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755878800; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs1207390245; called by muse, mutect2, varscan2
- RYR1 | c.10792G>A p.E3598K | Missense Mutation (SNP) | VAF 89/369 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); catalogued as rs1322440459, COSV100616015; called by muse, mutect2, varscan2
- RYR2 | c.13249G>A p.E4417K | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.098); catalogued as COSV63659164; called by muse, mutect2, varscan2
- S100A7 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs764601020, COSV64193332; called by muse, mutect2, varscan2
- SATL1 | c.886G>A p.E296K (on ENST00000395409; = p.E483K on NM_001012980.2) | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as rs1161475320, COSV60575587; called by muse, mutect2, varscan2
- SBSN | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 99/513 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs755643796; called by muse, mutect2, varscan2
- SC5D | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs199546863; called by muse, mutect2, varscan2
- SC5D | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs745380178, COSV50612677; called by muse, mutect2
- SCN10A | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 107/483 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs201068959, COSV71860875; called by muse, mutect2, varscan2
- SCN3A | c.3095G>A p.R1032K | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV51821263; called by muse, mutect2, varscan2
- SCN5A | c.6007G>A p.D2003N (on ENST00000333535 / NM_198056.3; = p.D2002N on NM_000335.5) | Missense Mutation (SNP) | VAF 106/437 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.36); catalogued as rs376697724, CM1515475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV69268332; called by muse, mutect2, varscan2
- SCN9A | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as COSV57620134; called by muse, mutect2, varscan2
- SCO1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 126/446 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs863224197; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK2 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 181/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1348884041; called by muse, mutect2, varscan2
- SEC24D | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1277871918; called by muse, mutect2, varscan2
- SEL1L3 | c.2957G>A p.G986E | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756402724; called by muse, mutect2, varscan2
- SEMG1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 148/382 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV54871876, COSV54872313; called by muse, mutect2, varscan2
- SEMG2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 114/536 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.355); catalogued as COSV65647261; called by muse, mutect2, varscan2
- SERPINA10 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 108/508 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs267604109, COSV56228009; called by muse, mutect2, varscan2
- SERPINA11 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 75/469 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs774059044; called by muse, mutect2, varscan2
- SERPINA7 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 73/210 reads (35%) | catalogued as COSV59667430; called by muse, mutect2, varscan2
- SFT2D3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 107/469 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.102); catalogued as rs546376182, COSV59256276; called by muse, mutect2, varscan2
- SIGLEC1 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 111/527 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1568846920; called by muse, mutect2, varscan2
- SIGLEC10 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 145/636 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs1160678579, COSV59479223; called by muse, mutect2, varscan2
- SIM1 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs1344055699, COSV53491298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIRPB1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV53539128, COSV53539741; called by muse, mutect2
- SLC10A2 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99807484; called by muse, mutect2, varscan2
- SLC12A6 | c.2051C>T p.S684F (on ENST00000354181 / NM_001365088.1; = p.S633F on NM_005135.2) | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51622756; called by muse, mutect2, varscan2
- SLC14A2 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs759799733, COSV54906829; called by muse, mutect2, varscan2
- SLC17A6 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 97/489 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs138159912, COSV54138373; called by muse, mutect2, varscan2
- SLC1A6 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 103/484 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as rs768085115; called by muse, mutect2, varscan2
- SLC22A10 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 76/380 reads (20%) | catalogued as COSV60420964; called by muse, mutect2, varscan2
- SLC26A7 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52590518; called by muse, mutect2, varscan2
- SLC27A6 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV52486714; called by muse, mutect2, varscan2
- SLC2A14 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 57/488 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs765545777; called by muse, mutect2, varscan2
- SLC39A10 | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 81/413 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); catalogued as rs769703215; called by muse, mutect2, varscan2
- SLC39A12 | c.1420A>C p.K474Q | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.077); catalogued as COSV66200537; called by muse, mutect2, varscan2
- SLC46A3 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57183786; called by muse, mutect2, varscan2
- SLC4A10 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 95/409 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV55773444; called by muse, mutect2, varscan2
- SLC5A9 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777949734; called by muse, mutect2, varscan2
- SLC8A3 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 96/429 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV63520273; called by muse, mutect2, varscan2
- SLCO1B3 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV53945248; called by muse, mutect2, varscan2
- SLCO2A1 | c.1464C>T p.I488= | Splice Region (SNP) | VAF 75/355 reads (21%) | catalogued as rs199651147; called by muse, mutect2, varscan2
- SLIT2 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 94/427 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV56560182; called by muse, mutect2, varscan2
- SMYD3 | c.1087C>T p.P363S (on ENST00000490107 / NM_001375962.1; = p.P304S on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/541 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs1488553220, COSV63625611; called by muse, mutect2
- SNIP1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 84/436 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1008679610, COSV56167527; called by muse, mutect2, varscan2
- SNX29 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1275653324, COSV60068841; called by muse, mutect2, varscan2
- SORL1 | c.4388C>T p.S1463F | Missense Mutation (SNP) | VAF 31/417 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs768288487; called by muse, mutect2
- SOX6 | c.1409G>A p.G470E (on ENST00000528429 / NM_001145819.2; = p.G429E on NM_017508.3) | Missense Mutation (SNP) | VAF 124/460 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs1274375949; called by muse, mutect2, varscan2
- SPAG11B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 83/531 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.973); catalogued as rs756967944, COSV52499921; called by muse, mutect2, varscan2
- SPARCL1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs1253908338, COSV56803735; called by muse, mutect2, varscan2
- SPHKAP | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 102/482 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs148914025, COSV60868610; called by muse, mutect2, varscan2
- SRSF11 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV63937871; called by muse, mutect2, varscan2
- SSTR3 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 121/600 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.215); catalogued as rs759921363; called by muse, mutect2, varscan2
- SSU72P8 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 172/421 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs747095129, COSV66361268; called by muse, mutect2, varscan2
- ST8SIA4 | c.246G>A p.R82= | Splice Region (SNP) | VAF 29/184 reads (16%) | catalogued as COSV104371243, COSV51515442; called by muse, mutect2, varscan2
- STIM1 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 122/573 reads (21%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs376050145; called by muse, mutect2, varscan2
- STPG3 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 127/581 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs751494214; called by muse, mutect2, varscan2
- SULF2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 74/423 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577311137, COSV100737540; called by muse, mutect2, varscan2
- SUPT20H | c.1154C>T p.S385L (on ENST00000350612 / NM_001014286.3; = p.S386L on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.033); catalogued as rs1483853749, COSV62247125; called by muse, mutect2, varscan2
- SUSD5 | c.411G>A p.E137= | Splice Region (SNP) | VAF 70/301 reads (23%) | catalogued as COSV58875561; called by muse, mutect2, varscan2
- SYNE1 | c.533G>A p.G178E (on ENST00000367255 / NM_182961.4; = p.G185E on NM_033071.3) | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868413668, COSV55053512; called by muse, mutect2, varscan2
- TAAR6 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 101/450 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV51583234; called by muse, mutect2, varscan2
- TACR1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 39/563 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776833375; called by muse, mutect2
- TACR3 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 73/396 reads (18%) | catalogued as rs1228465213, COSV100510322; called by muse, mutect2, varscan2
- TAF1L | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 132/586 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs765930570, COSV54256386; called by muse, mutect2, varscan2
- TAS2R41 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 96/597 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.485); catalogued as rs546304222, COSV68764991; called by muse, mutect2, varscan2
- TAT | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747367241, COSV63533120; called by muse, mutect2, varscan2
- TAT | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs1244015119; called by muse, mutect2, varscan2
- TCHHL1 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV64286727; called by muse, mutect2
- TENM1 | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64433391; called by muse, mutect2, varscan2
- TENM3 | c.6256C>T p.R2086C | Missense Mutation (SNP) | VAF 98/456 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778320384, COSV69307925; called by muse, mutect2, varscan2
- TENM4 | c.6745G>A p.G2249S | Missense Mutation (SNP) | VAF 114/471 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs186319631; called by muse, mutect2, varscan2
- TENT5D | c.1021A>G p.N341D | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as rs1200263892; called by muse, mutect2, varscan2
- TEX26 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66839480; called by muse, mutect2, varscan2
- TEX52 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 88/396 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1368510737, COSV61206535; called by mutect2, varscan2
- THBS2 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 104/488 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.964); catalogued as rs1474976569; called by muse, varscan2
- THNSL2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 22/453 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs964320373, COSV59084671; called by muse, mutect2
- THSD7B | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as COSV55725275; called by muse, mutect2, varscan2
- THSD7B | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs1347902701, COSV55656405; called by muse, varscan2
- TIFAB | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs780085168; called by muse, mutect2, varscan2
- TIMM44 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 85/395 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1352281392; called by muse, mutect2, varscan2
- TKTL2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV54919578; called by muse, mutect2, varscan2
- TLL1 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 99/401 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as rs1187333124; called by muse, mutect2, varscan2
- TM4SF5 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 85/347 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV54495787; called by muse, mutect2, varscan2
- TMEM108 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 104/432 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV58869483; called by muse, mutect2, varscan2
- TMEM176A | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 92/380 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV50242812; called by muse, mutect2, varscan2
- TMEM184C | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99669646, COSV99669722; called by muse, mutect2, varscan2
- TMEM94 | c.3324C>T p.F1108= | Splice Region (SNP) | VAF 117/284 reads (41%) | catalogued as rs1161117430; called by muse, mutect2, varscan2
- TMPRSS15 | c.1684A>T p.K562* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as COSV53039085; called by muse, mutect2, varscan2
- TMTC4 | c.1638G>A p.Q546= (on ENST00000376234 / NM_001350577.2; = p.Q565= on NM_032813.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 58/283 reads (20%) | catalogued as COSV60891979; called by muse, mutect2, varscan2
- TNFRSF10A | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as rs754090248, COSV99646158, COSV99646318; called by muse, mutect2, varscan2
- TNFRSF10C | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 114/674 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs749334327; called by muse, varscan2
- TNN | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 32/475 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.037); catalogued as rs1309039795, COSV53421169, COSV53432845; called by muse, mutect2
- TNN | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 125/653 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs755253081; called by muse, mutect2, varscan2
- TNNT2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 168/465 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs929267187, COSV52665346; called by muse, mutect2, varscan2
- TNR | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs1176098520; called by muse, mutect2, varscan2
- TNRC18 | c.6389C>T p.S2130F | Missense Mutation (SNP) | VAF 136/517 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1196293883, COSV60308945; called by muse, mutect2, varscan2
- TOX2 | c.1451C>T p.S484L (on ENST00000358131 / NM_001098798.2; = p.S460L on NM_032883.3) | Missense Mutation (SNP) | VAF 80/415 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs779716371, COSV57883132; called by muse, mutect2, varscan2
- TPO | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 106/492 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61097095; called by muse, varscan2
- TPO | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 119/506 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as COSV61112589; called by muse, varscan2
- TPRG1 | c.303G>A p.K101= | Splice Region (SNP) | VAF 53/210 reads (25%) | catalogued as COSV61464582; called by muse, mutect2, varscan2
- TPRG1 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1202654678; called by muse, mutect2, varscan2
- TPTE | c.1340C>T p.S447L (on ENST00000618007 / NM_199261.4; = p.S429L on NM_199259.4) | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs759301774; called by muse, mutect2
- TRAF3IP3 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 121/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766448268, COSV50550440; called by muse, mutect2, varscan2
- TRAPPC3L | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 95/376 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs898564008; called by muse, mutect2, varscan2
- TREH | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs549870419; called by muse, mutect2, varscan2
- TRIP11 | c.5762C>T p.P1921L | Missense Mutation (SNP) | VAF 74/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs368950450; called by muse, mutect2, varscan2
- TRPC3 | c.739G>A p.E247K (on ENST00000379645 / NM_001366479.2; = p.E174K on NM_003305.2) | Missense Mutation (SNP) | VAF 116/514 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868163943, COSV53377777; called by muse, mutect2, varscan2
- TRPM6 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV62513789; called by muse, mutect2
- TRPM8 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61221528; called by muse, mutect2, varscan2
- TSPAN2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as COSV65689912; called by muse, mutect2, varscan2
- TSSC4 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 80/491 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs763999896; called by muse, mutect2, varscan2
- TTF1 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as rs1399490933; called by muse, mutect2, varscan2
- TTLL5 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs562332993, COSV54047296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB8B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 42/579 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1259203799; called by muse, mutect2
- UAP1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 104/619 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1009696314; called by muse, mutect2, varscan2
- UGT1A6 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 120/493 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs139410055; called by muse, mutect2, varscan2
- UGT2B15 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1263517739, COSV57735948; called by muse, mutect2, varscan2
- UGT2B28 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV59431371; called by muse, mutect2, varscan2
- UNC13C | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52860266; called by muse, mutect2, varscan2
- USP54 | c.2666C>A p.S889Y | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100357125; called by muse, mutect2, varscan2
- USP6 | c.4174G>A p.D1392N | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100002726; called by muse, mutect2, varscan2
- VCAN | c.10079G>A p.R3360K | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54097674; called by muse, mutect2, varscan2
- VIP | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 96/327 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV65888939; called by muse, mutect2, varscan2
- VPS13B | c.5359C>T p.R1787C | Missense Mutation (SNP) | VAF 92/348 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs780314338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13C | c.1084C>T p.P362S (on ENST00000644861 / NM_020821.3; = p.P319S on NM_017684.5) | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1200532810; called by muse, mutect2, varscan2
- VPS37D | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 103/574 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV61446260; called by muse, mutect2, varscan2
- VWA5A | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs372417602, COSV64413621; called by muse, mutect2, varscan2
- WDFY4 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 96/407 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1272105655; called by muse, varscan2
- WDFY4 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs866447241, COSV100304558; called by muse, mutect2, varscan2
- WDR49 | c.1627G>A p.E543K (on ENST00000308378 / NM_001366158.1; = p.E884K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs867011458, COSV57706145; called by muse, mutect2, varscan2
- WDR87 | c.8350C>T p.Q2784* | Nonsense Mutation (SNP) | VAF 100/412 reads (24%) | catalogued as COSV58207399; called by muse, mutect2, varscan2
- WDR87 | c.2489G>A p.R830K | Missense Mutation (SNP) | VAF 65/400 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.327); catalogued as rs897259020; called by muse, mutect2, varscan2
- WIPF1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 77/488 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs759799376, COSV55811800; called by muse, mutect2, varscan2
- WNT5A | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 83/445 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52835987; called by muse, mutect2, varscan2
- WRNIP1 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867029038, COSV66356158; called by muse, mutect2
- XKR9 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs867404674; called by muse, mutect2, varscan2
- ZAR1L | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV61525236; called by muse, varscan2
- ZBBX | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56788773; called by muse, mutect2, varscan2
- ZBTB25 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 107/455 reads (24%) | catalogued as rs866861977, COSV101170755; called by muse, mutect2, varscan2
- ZDHHC11B | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1450642232; called by muse, mutect2, varscan2
- ZEB1 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 89/414 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV58044464; called by muse, varscan2
- ZFHX3 | c.4255C>T p.H1419Y | Missense Mutation (SNP) | VAF 122/456 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1447637213; called by muse, mutect2, varscan2
- ZFP91 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 58/307 reads (19%) | catalogued as COSV60157197; called by muse, mutect2, varscan2
- ZNF208 | c.2479C>T p.H827Y | Missense Mutation (SNP) | VAF 82/481 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV68104736; called by muse, mutect2, varscan2
- ZNF253 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63037191; called by muse, mutect2, varscan2
- ZNF257 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV71308086, COSV71309482; called by muse, mutect2, varscan2
- ZNF280A | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 90/461 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as rs758626138; called by muse, mutect2, varscan2
- ZNF334 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 91/505 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100749096; called by muse, mutect2, varscan2
- ZNF33B | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63942025; called by muse, mutect2, varscan2
- ZNF385D | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99875791; called by muse, mutect2, varscan2
- ZNF469 | c.8990G>A p.R2997K (on ENST00000437464; = p.R3025K on NM_001367624.2) | Missense Mutation (SNP) | VAF 132/645 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs548681380, COSV71258330; called by muse, mutect2, varscan2
- ZNF496 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 222/609 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs533663170, COSV54176170; called by muse, mutect2, varscan2
- ZNF556 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 99/462 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV56912226; called by muse, mutect2, varscan2
- ZNF560 | c.1625G>A p.R542K | Missense Mutation (SNP) | VAF 99/408 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs769335798, COSV56866151; called by muse, mutect2, varscan2
- ZNF573 | c.1742C>T p.P581L (on ENST00000536220 / NM_001172692.1; = p.P523L on NM_152360.3) | Missense Mutation (SNP) | VAF 89/341 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59823687; called by muse, mutect2, varscan2
- ZNF619 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 77/375 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV59031353; called by muse, mutect2, varscan2
- ZNF723 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.164); catalogued as rs796317212; called by muse, varscan2
- ZNF837 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 122/549 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.219); catalogued as rs1159784232; called by muse, mutect2, varscan2
- ZNF846 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 129/493 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV67411982; called by muse, mutect2, varscan2
- ZPBP | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250479; called by muse, mutect2, varscan2
- ZSCAN5C | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.646); catalogued as rs1397299677; called by muse, mutect2, varscan2
- ABCA12 | c.2885C>T p.S962F (on ENST00000272895 / NM_173076.3; = p.S644F on NM_015657.3) | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ABCA13 | c.15101C>T p.S5034F | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ABCA2 | c.1235C>T p.T412I (on ENST00000614293; = p.T382I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/637 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ABCB10 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 69/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ABCC2 | c.4276T>G p.L1426V | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC4 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCC6 | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABI1 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 100/413 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AC005551.1 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 46/628 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- AC099489.1 | c.8602G>A p.E2868K | Missense Mutation (SNP) | VAF 89/403 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ACP4 | c.1241G>A p.W414* | Nonsense Mutation (SNP) | VAF 103/524 reads (20%) | called by muse, mutect2, varscan2
- ACRBP | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 142/557 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ACSM2A | c.1457C>T p.P486L (on ENST00000219054; = p.P407L on NM_001308169.2) | Missense Mutation (SNP) | VAF 89/425 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ACTR3B | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.094); called by muse, mutect2
- ADAMTS18 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 82/397 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.782T>A p.F261Y | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
1,456 further variants in this file (672 protein-altering or splice-affecting, 713 silent, 71 other) are not listed here.
